Somatic mutation profile of tumor specimen TARGET-20-PASLSE-03A (aliquot TARGET-20-PASLSE-03A-01D) from TARGET case TARGET-20-PASLSE, project TARGET-AML (Acute Myeloid Leukemia). Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow.
Specimen TARGET-20-PASLSE-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac9c01f5-5a89-41b1-91ae-7131f752b50e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASLSE-14A (Bone Marrow Normal), aliquot TARGET-20-PASLSE-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f294a38f-befe-4dec-86d2-c55e6a8a4a77

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Frame Shift Ins 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 42/151 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FAT1 | c.5854G>A p.V1952I | Missense Mutation (SNP) | VAF 80/295 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs762168387, COSV71675788; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCATG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 8/40 reads (20%) | catalogued as rs1554138188, COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, pindel, varscan2
- NPAP1 | c.*1357G>T | 3'UTR (SNP) | VAF 31/120 reads (26%) | called by muse, mutect2, varscan2
- POLR2A | c.-44T>G | 5'UTR (SNP) | VAF 10/46 reads (22%) | catalogued as rs753052351; called by muse, mutect2, varscan2
